Gene-level copy-number profile of tumor specimen TCGA-22-A5C4-01A from TCGA case TCGA-22-A5C4, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.2 years (25,629 days).
Specimen TCGA-22-A5C4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.613ef390-7733-4061-84ef-9c7718c44462.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-A5C4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5879524f-3a13-4502-92aa-3a938df074ef

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 942; copy number 2: 13,195; copy number 3: 23,170; copy number 4: 13,110; copy number 5: 4,586; copy number 6: 1,812; copy number 7: 853; copy number 8: 843; copy number 9: 480; copy number 10: 121; copy number 11: 263; copy number 12: 238; copy number 13: 63; copy number 15: 13; copy number 16: 13; copy number 19: 8; copy number 23: 3; copy number 24: 19; copy number 26: 18; copy number 31: 11; copy number 43: 17; copy number 44: 33; copy number 56: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-A5C4-01A-12D-A27J-01): tumor purity 0.68, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,880 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–2,817,767, 173 genes, copy number 11 (broad region; genes not listed).
- chr2:57,544,535–69,674,349, 219 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr2:96,497,646–98,398,601, 60 genes, copy number 8: NEURL3, AC013270.1, ARID5A, KANSL3, FER1L5, LMAN2L, CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P, ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1, AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2.
- chr2:149,587,196–150,047,447, 1 gene, copy number 9 (within-gene range 2–9): MMADHC-DT.
- chr2:149,745,648–151,186,595, 13 genes, copy number 9: LINC01931, AC016682.1, LINC01818, LINC01817, RND3, LINC01920, AC104777.2, AC104777.1, LINC02612, AC023469.2, AC023469.1, AC018731.1, FABP5P10.
- chr2:153,871,922–161,160,224, 91 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).
- chr2:165,194,993–165,436,614, 3 genes, copy number 12 (within-gene range 5–13): SCN2A, MAPRE1P3, AC011303.1.
- chr2:170,813,213–173,368,997, 42 genes, copy number 7: GAD1, AC007405.2, AC007405.4, AC010092.1, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7.
- chr4:9,692,495–10,200,672, 17 genes, copy number 9: FAM86MP, ALG1L3P, Metazoa_SRP, AC098976.1, OR7E35P, SLC2A9, DRD5, RNA5SP154, AC108199.1, SLC2A9-AS1, AC005674.1, WDR1, MIR3138, RNA5SP155, AC093664.1, AC006499.6, AC006499.1.
- chr4:13,051,342–14,003,756, 14 genes, copy number 8: U6, HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1, AC095052.1.
- chr4:15,681,756–16,320,140, 15 genes, copy number 9 (within-gene range 3–9): AC114744.2, BST1, AC114744.1, AC005798.1, CD38, HPRT1P1, FGFBP1, FGFBP2, PROM1, AC108063.2, TAPT1, AC108063.1, TAPT1-AS1, RPS21P4, AC006427.1.
- chr4:17,800,655–18,021,876, 4 genes, copy number 7: DCAF16, NCAPG, LCORL, KRT18P63.
- chr4:19,747,179–20,037,972, 3 genes, copy number 7: AC110767.1, AC114728.1, AC098862.1.
- chr4:25,648,011–27,282,225, 25 genes, copy number 8–13: SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4, AC024132.2, AC024132.1, LINC02261, Y_RNA, AC024132.3.
- chr4:30,884,443–31,558,831, 4 genes, copy number 8 (within-gene range 5–8): MTCYBP43, LINC02497, AC104071.1, LINC02501.
- chr4:35,487,812–37,821,838, 21 genes, copy number 7: SEC63P2, RNU6-573P, ARAP2, AC098827.1, AC104078.1, DTHD1, AC104078.2, MIR1255B1, LINC02505, AC125336.1, AC093746.1, LINC02616, AL136537.1, MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1.
- chr4:38,276,178–39,528,311, 31 genes, copy number 7: AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3, RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574, TMEM156, KLHL5, AC079921.1, AC079921.2, WDR19, RFC1, RNU6-32P, RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1, UGDH.
- chr4:40,743,627–41,303,337, 12 genes, copy number 8–11: AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA.
- chr4:41,688,858–45,480,136, 52 genes, copy number 7: AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82, GRXCR1, AC111198.1, AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P.
- chr4:48,490,252–48,780,322, 3 genes, copy number 12 (within-gene range 4–12): ZAR1, FRYL, RNU5E-3P.
- chr4:52,252,820–54,295,272, 25 genes, copy number 7 (within-gene range 4–7): AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2.
- chr4:54,059,597–56,603,507, 58 genes, copy number 7–9 (within-gene range 4–9): AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL.
- chr4:57,154,577–59,180,414, 18 genes, copy number 7: AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1.
- chr4:75,101,477–75,941,013, 18 genes, copy number 7–11: AC110760.2, AC093870.1, AC025244.1, AC025244.2, LINC02483, AC096759.1, AC096759.2, RCHY1, THAP6, ODAPH, CDKL2, G3BP2, Y_RNA, USO1, AC110615.1, RNU2-16P, PPEF2, NAAA.
- chr5:58,198–45,895,970, 710 genes, copy number 7–8 (broad region; genes not listed).
- chr6:72,522,641–73,310,365, 16 genes, copy number 12–19: FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1.
- chr7:29,912,528–30,179,014, 13 genes, copy number 8: AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1.
- chr7:32,427,901–32,495,283, 4 genes, copy number 8: AC018637.1, AC018641.1, SLC25A5P5, LSM5.
- chr8:37,597,480–42,555,195, 125 genes, copy number 8–44 (broad region; genes not listed).
- chr12:69,400,903–71,441,898, 32 genes, copy number 31–56 (within-gene range 3–56): RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8.
- chr16:10,944,564–11,182,186, 1 gene, copy number 26 (within-gene range 3–26): CLEC16A.
- chr16:11,066,496–12,881,493, 56 genes, copy number 11–26: AC007014.1, AC007220.2, AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4, SNX29, AC007216.1, RPS23P6, AC007601.1, AC007601.2, AC092365.1, AC007598.2, AC007598.1, AC007598.3, AC131391.1, AC010333.1, AC010333.2, AC010333.3, CPPED1, MIR4718, AC109597.1, AC109597.2, AC092324.1, RPL35AP34.
- chr16:15,358,978–15,857,028, 16 genes, copy number 16–23 (within-gene range 3–23): AC137803.1, NPIPA5, MPV17L, AC140504.1, BMERB1, MARF1, AC026401.1, MIR6506, NDE1, MIR484, AC026401.2, AC026401.3, MYH11, AF001548.2, AF001548.1, AF001548.3.
- chr20:1,266,280–3,039,076, 61 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:5,937,228–11,345,855, 72 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:30,278,906–45,641,370, 430 genes, copy number 7–10 (broad region; genes not listed).
- chr21:16,284,696–16,873,691, 12 genes, copy number 7: SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1.
- chr21:35,472,095–39,515,506, 107 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr22:15,290,718–17,081,456, 78 genes, copy number 9 (broad region; genes not listed).
- chr22:20,859,007–23,318,037, 220 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 665. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
